Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A5VD, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A5VD-01A (Primary Tumor).

TSS DelD:
Surgery Date:

SPECIMENS:

A. WIDE EXCISION LEFT ANKLE SUBCUTANEOUS LEIOMYOSARCOMA

DIAGNOSIS:

A. SKIN, LEFT ANKLE, WIDE LOCAL EXCISION:
-CUTANEOUS LEIOMYOSARCOMA, LOW-GRADE, MEASURING 2.0 X 1.6 CM, INVOLVING
DERMIS AND SUPERFICIAL SUBCUTANEOUS TISSUE
-SURGICAL MARGINS NEGATIVE FOR SARCOMA

Note: Dr. reviewed selected slides and agrees with the above diagnosis.

GROSS DESCRIPTION:

A. WIDE EXCISION LEFT ANKLE SUBCUTANEOUS LEIOMYOSARCOMA
Received fresh labeled with the patient's identification and designated "wide excision left ankle subcutaneous leiomyosarcoma" is an oriented excision of tan-white skin measuring 4.4 x 1.2 cm, excised to a depth of 1.2 cm. The stitch designates the proximal margin. Ink code: Proximal-lateral-distal - blue, distal-medial-proximal - black. The surface of the specimen demonstrates a tan-white, indurated and raised lesion measuring 2 x 1.6 cm, located 0.9 cm from the nearest distal margin. The specimen is serially sectioned from proximal to distal. Gross photos are taken and a portion of the specimen is admitted for tissue procurement. The entire specimen is submitted as follows:

A1: proximal tip
A2-A3: Serial sections
A4-A8: Serial sections demonstrating lesion
A9-A10: Serial sections
A11: Distal tip.

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Leiomyosarcoma left lower leg.

ICD-O-3
Leiomyosarcoma, NOS 8890/3
Site ^{path} Connective, subcutaneous
and other soft tissues ankle
C49.2
Connective, subcutaneous and other
soft tissues of extremities
C49.9
JW 4/12/13

Prior Malignancy/History		

Source: NCI Genomic Data Commons file 67c24ced-d579-4140-895d-225858b4beb6 (TCGA-QQ-A5VD.70E1DE9E-83E9-4384-9810-652726DEDB9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).